Surgical pathology report (de-identified scan), TCGA case TCGA-ZJ-AAXA, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site NCI HRE Branch, specimen TCGA-ZJ-AAXA-01A (Primary Tumor).

[page 1 of 2]
ACCT#: [REDACTED] DOB: [REDACTED]

Specimen #:

Date Obtained:

Date Received:

Dr:

Date Printed:

CLINICAL HISTORY:

ICD-9: 233.1

SPECIMEN/PROCEDURE:

1. CERVIX - CONE
2. ENDOCERVIX/ECC

ICD-O-3

*Carcinoma, squamous cell, non
keratinizing NOS 8072/3
Site: Cervix NOS C53.9
Q26/3/14*

IMPRESSION:

- 1) CERVICAL CONE:
- . Squamous cell carcinoma, large cell nonkeratinizing, Grade 2, with stromal invasion involving the cervix circumferentially as well as the deep and endocervical margins.
- . The tumor measures at least 7.0 mm in depth and at least 10.0 mm in lateral extension. Tumor is present in all sections.
- . Vascular space invasion is focally identified.
- 2) ENDOCERVICAL CURETTINGS:
- . Blood clot with scant fragments of squamous cell carcinoma.

Dictated by: [REDACTED]

Entered: [REDACTED]

GROSS DESCRIPTION:

This case is part of the

1. Received in formalin labeled "cervical cone" and with the patient's name, is an irregular cervical LEEP, 2 x 2 x 1.9 cm. The epithelial surface, is deep red glistening and granular. There is a black suture marking the 12:00 aspect of the specimen. The specimen is submitted as 12:00 and 6:00 per the . The specimen is inked blue on the endocervix, and black on the ectocervix. The specimen is radially serially sectioned and entirely submitted in 10 cassettes cassettes as follows:

Cassette 1A: 1:00
Cassette 1B: 2:00
Cassette 1C: 3:00
Cassette 1D: 4:00
Cassette 1E: 5:00
Cassette 1G: 7:00

Patient: [REDACTED]	Age/Sex: /F	Acct# [REDACTED]	Unit# [REDACTED]
---------------------	-------------	------------------	------------------

[page 2 of 2]
Specimen #: _____ DOB: _____
Obtained: _____ (Continued) Page: 2

GROSS DESCRIPTION: (continued)

Cassette 1H: 8:00

Cassette 1J: 9:00

Cassette 1K: 10:00L: 11:00

2. Received in formalin labeled "endometrial curettings" and with the patient's name, is an aggregate of deep red to deep purple glistening tissue, consistent blood clot 2 x 2 by 0.3 cm. The specimen is entirely submitted in one cassette.

Dictated by:

Entered:

CPT Codes:

CERVICAL CONE/88307, ENDOCERVICAL BX/ 88305

ICD9 Codes:

180.9

Electronically Signed by: _____

Patient: _____ Age/Sex: /F Acct# _____ Unit: _____

Source: NCI Genomic Data Commons file c929ea30-d7ec-4a5f-82e1-32e530b2f6b7 (TCGA-ZJ-AAXA.01EB0759-6676-494E-9044-263629A7BD93.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).